Somatic mutation profile of tumor specimen TCGA-AX-A2HD-01A (aliquot TCGA-AX-A2HD-01A-21D-A17D-09) from TCGA case TCGA-AX-A2HD, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 69.8 years (25,499 days).
Specimen TCGA-AX-A2HD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02931d86-ee62-4625-83e9-b810118a18ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A2HD-11A (Solid Tissue Normal), aliquot TCGA-AX-A2HD-11A-11D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acb88107-fc9f-435d-a355-815e070b5dd7

The open-access MAF lists 9,806 somatic variants for this specimen: 7,029 protein-altering or splice-affecting, 2,549 silent, 228 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6,088, Silent 2,549, Nonsense Mutation 382, Frame Shift Del 246, Splice Site 115, Frame Shift Ins 103, Intron 97, Splice Region 81, RNA 54, 5'Flank 25, 3'UTR 22, 5'UTR 16.

Variants (750 of 9,806; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.609dup p.A204Cfs*39 | Frame Shift Ins (INS) | VAF 29/78 reads (37%) | catalogued as rs1562988165; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACTG2 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as rs587777386, CM143759, COSV100609175; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHI1 | c.910dup p.T304Nfs*6 | Frame Shift Ins (INS) | VAF 11/24 reads (46%) | catalogued as rs753874898; ClinVar: pathogenic; called by mutect2, varscan2
- ALDH18A1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863225044, CM159181, COSV64662240; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALMS1 | c.10822C>T p.R3608* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as rs1192396248, CM074692, COSV100041495; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- AR | c.2612C>T p.A871V | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (1); PolyPhen possibly damaging (0.796); catalogued as rs143040492, CM940093, CM973708, CM980115, COSV65957981; ClinVar: pathogenic; called by muse, mutect2
- ARSL | c.1442C>T p.T481M | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs80338713, CM030775, COSV101140517; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 46/93 reads (49%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ATM | c.1880dup p.Q628Pfs*7 | Frame Shift Ins (INS) | VAF 28/73 reads (38%) | catalogued as rs786202474; ClinVar: pathogenic; called by pindel, varscan2
- BRCA2 | c.2957del p.N986Ifs*5 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs80359365; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRCA2 | c.5073del p.K1691Nfs*15 | Frame Shift Del (DEL) | VAF 21/43 reads (49%) | catalogued as rs80359479; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- BUB1B | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 24/58 reads (41%) | catalogued as rs769350713, COSV99806886; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CARD14 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs281875215, CM1213173, CS123490, COSV100712560, COSV60124009; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- CDH1 | c.1993del p.I665Sfs*14 | Frame Shift Del (DEL) | VAF 26/45 reads (58%) | catalogued as rs1567513227; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CLCN2 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as rs863225250, COSV99658572; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL18A1 | c.3918dup p.G1307Rfs*9 (on ENST00000359759 / NM_130444.3; = p.G1072Rfs*9 on NM_030582.4) | Frame Shift Ins (INS) | VAF 28/68 reads (41%) | catalogued as rs749009747; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CTNNB1 | c.1149G>T p.W383C | Missense Mutation (SNP) | VAF 27/69 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV62692553, COSV62700446, COSV62722790; called by muse, mutect2, varscan2
- DEPDC5 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as rs886039255, CM164373, COSV99835332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DEPDC5 | c.2386C>T p.R796* (on ENST00000400246; = p.R865* on NM_014662.5) | Nonsense Mutation (SNP) | VAF 39/99 reads (39%) | catalogued as rs578185749, CM146221, COSV99835340; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs794728162, CM045409, CM094367, COSV57313386; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- FSHB | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 21/33 reads (64%) | catalogued as rs374623109, COSV54221612; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GATA6 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906818, CM1110613, COSV52526905; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GJA5 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs387906613, CM104883, COSV99605540; ClinVar: pathogenic; called by muse, varscan2
- GNE | c.124C>T p.R42W (on ENST00000396594 / NM_001128227.3; = p.R11W on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs769716748, CM043290, COSV64952198; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GRM7 | c.1972C>T p.R658W | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1114167300, COSV63153106; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNQ3 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as rs796052675, COSV66479891; ClinVar: pathogenic; called by muse, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 40/73 reads (55%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- MYO7A | c.5581C>T p.R1861* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as rs878864531, CM971017, COSV101289130; ClinVar: pathogenic; called by muse, varscan2
- NPHS1 | c.2479C>T p.R827* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | catalogued as rs140018064, CM044915; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OPLAH | c.2608del p.H870Tfs*28 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | catalogued as rs781956288; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PDHA1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs137853252, CM920575, COSV100134711, COSV100135217; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 22/57 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1064793663, COSV55877982, COSV55886419, COSV56022812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PKD1 | c.1396G>A p.V466M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs2855341, COSV99238104; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PKHD1 | c.1774C>T p.R592* | Nonsense Mutation (SNP) | VAF 40/72 reads (56%) | catalogued as rs779050294, CM051131, COSV100583069; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PLCB4 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397514482, CM123398, COSV53801196, COSV99595451; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLG | c.2419C>T p.R807C | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769827124, CM064164, COSV51520376; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- POMGNT1 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 45/91 reads (49%) | catalogued as rs386834034, CM123372, COSV100915579; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- POMT2 | c.1057G>A p.G353S | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs267606970, CM063065, COSV55069388; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.40dup p.R14Kfs*30 | Frame Shift Ins (INS) | VAF 28/86 reads (33%) | catalogued as rs587776671; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.1026+1G>A p.X342_splice | Splice Site (SNP) | VAF 29/61 reads (48%) | hotspot (GDC flag); catalogued as rs786201041, CS043794, CS110216, COSV64288702, COSV64289135, COSV64293873; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PYCR2 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs149587849, COSV100661511; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1422-1G>A p.X474_splice | Splice Site (SNP) | VAF 4/14 reads (29%) | hotspot (GDC flag); catalogued as rs1461382798, CS058009, CS1312472, COSV57314130, COSV99926204; ClinVar: pathogenic; called by muse, varscan2
- RYR2 | c.7159G>A p.A2387T | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs794728753, CM056386, HM030024, COSV100770091; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.3968C>A p.P1323H (on ENST00000303395 / NM_001202435.3; = p.P1312H on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057521746, CD100966, CM117669, COSV57679338; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SDHB | c.724C>A p.R242S | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786203251, CM041829, CM092170, COSV100973407; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMC1A | c.3196C>T p.R1066C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs797044896, CM1515029, COSV59128172; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAT5B | c.1102dup p.Q368Pfs*9 | Frame Shift Ins (INS) | VAF 26/59 reads (44%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- STXBP1 | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs796053373, CM125342, CM1513639, COSV64813774; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TNNI3 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs397516349, CM971497, COSV52572698; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.254del p.P85Lfs*38 | Frame Shift Del (DEL) | VAF 30/61 reads (49%) | catalogued as rs1064793279, COSV53087170; ClinVar: pathogenic; called by mutect2, varscan2
- USP9X | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as rs869025592, CM161665, COSV61071116; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VDR | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 83/166 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs121909791, CM880064, COSV57469302; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- VIPAS39 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as rs200370925, CM101901, COSV58938805; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.2440G>A p.V814I | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV59389182; called by muse, mutect2, varscan2
- A2M | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 30/78 reads (38%) | catalogued as COSV100588674; called by muse, mutect2, varscan2
- A2ML1 | c.2175G>T p.E725D | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100228926; called by muse, mutect2, varscan2
- AADACL4 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs773606956, COSV66105868; called by muse, mutect2, varscan2
- AARS1 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as rs1301433529, COSV99933500; called by muse, mutect2, varscan2
- AARS2 | c.2368C>T p.R790* | Nonsense Mutation (SNP) | VAF 29/58 reads (50%) | catalogued as rs1480490090, COSV99771302; called by muse, mutect2, varscan2
- AARS2 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as rs747514149, COSV55113269; called by muse, varscan2
- AASS | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141405677; called by muse, mutect2, varscan2
- ABCA12 | c.4114C>T p.H1372Y (on ENST00000272895 / NM_173076.3; = p.H1054Y on NM_015657.3) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs945688014, COSV99789891; called by muse, mutect2, varscan2
- ABCA12 | c.3991T>C p.F1331L (on ENST00000272895 / NM_173076.3; = p.F1013L on NM_015657.3) | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV99789895; called by muse, mutect2, varscan2
- ABCA12 | c.2974G>A p.A992T (on ENST00000272895 / NM_173076.3; = p.A674T on NM_015657.3) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0.021); catalogued as COSV55959675; called by muse, mutect2, varscan2
- ABCA12 | c.872G>A p.S291N | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV55973276, COSV99789901; called by muse, mutect2, varscan2
- ABCA13 | c.7735del p.I2579* | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as COSV71288654; called by mutect2, varscan2
- ABCA13 | c.9652G>A p.A3218T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.199); catalogued as rs1434711013, COSV101446955; called by muse, mutect2, varscan2
- ABCA13 | c.10253G>A p.R3418H | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs764681827, COSV71287219, COSV71287487; called by muse, mutect2, varscan2
- ABCA2 | c.6548C>T p.T2183M (on ENST00000614293; = p.T2153M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1437397894, COSV99687599; called by muse, mutect2, varscan2
- ABCA2 | c.664C>T p.H222Y (on ENST00000614293; = p.H192Y on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.138); catalogued as COSV99687604; called by muse, mutect2, varscan2
- ABCA2 | c.574C>A p.L192I (on ENST00000614293; = p.L162I on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as COSV99687606; called by muse, mutect2, varscan2
- ABCA4 | c.6250G>A p.A2084T | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250914690, COSV64671514, COSV64677755; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA5 | c.2350G>A p.V784I | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs150760061; called by muse, mutect2, varscan2
- ABCA6 | c.3770C>T p.T1257I | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99446458; called by muse, mutect2, varscan2
- ABCA6 | c.900A>G p.I300M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV99446463; called by muse, mutect2, varscan2
- ABCA7 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.22); catalogued as COSV99565761; called by muse, mutect2, varscan2
- ABCA7 | c.3757G>A p.A1253T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1452730163, COSV99565763; called by muse, mutect2, varscan2
- ABCA7 | c.4454C>T p.A1485V | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV99565764; called by muse, mutect2, varscan2
- ABCA8 | c.2353C>A p.L785I | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as COSV99285735; called by muse, mutect2, varscan2
- ABCA8 | c.1351G>A p.V451M | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as rs746721593, COSV99285738; called by muse, mutect2, varscan2
- ABCB5 | c.1600G>A p.A534T (on ENST00000404938 / NM_001163941.2; = p.A89T on NM_178559.6) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs745873483, COSV51704716; called by muse, mutect2, varscan2
- ABCB6 | c.977T>C p.V326A | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV99521845; called by muse, mutect2, varscan2
- ABCB9 | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as rs149734521; called by muse, mutect2, varscan2
- ABCC1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as rs559703047, COSV60680245; called by muse, mutect2, varscan2
- ABCC10 | c.2974G>T p.G992C (on ENST00000372530 / NM_001198934.2; = p.G964C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99767250; called by muse, mutect2, varscan2
- ABCC10 | c.4400G>A p.R1467H (on ENST00000372530 / NM_001198934.2; = p.R1439H on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs762227822, COSV55096107; called by muse, mutect2, varscan2
- ABCC11 | c.984G>T p.Q328H | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV100750762, COSV62322134; called by muse, mutect2, varscan2
- ABCC12 | c.4017A>C p.E1339D | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV60911313; called by muse, mutect2, varscan2
- ABCC12 | c.2010A>T p.E670D | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV100252684; called by muse, mutect2, varscan2
- ABCC2 | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs200570593, COSV100965602; called by muse, varscan2
- ABCC2 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs147494662; ClinVar: uncertain significance; called by muse, varscan2
- ABCC3 | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 37/83 reads (45%) | catalogued as rs746171655, COSV99559140; called by muse, mutect2, varscan2
- ABCC3 | c.2527G>A p.G843S | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs759454160, COSV53321951; called by muse, mutect2, varscan2
- ABCC5 | c.2555C>A p.A852D | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV99656895; called by muse, mutect2, varscan2
- ABCC5 | c.1397G>A p.R466K | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV99656898; called by muse, mutect2, varscan2
- ABCC8 | c.4177C>T p.R1393C | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776610373, COSV56855567; called by muse, mutect2, varscan2
- ABCC8 | c.3073G>A p.V1025I | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as rs771882862, COSV100217251; called by muse, mutect2, varscan2
- ABCC8 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs767822371, COSV100217253; called by muse, mutect2, varscan2
- ABCD1 | c.1591C>A p.L531I | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV99497552; called by muse, mutect2, varscan2
- ABCD2 | c.1711C>T p.H571Y | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV100429442; called by muse, mutect2, varscan2
- ABCF1 | c.1826C>T p.T609I (on ENST00000326195 / NM_001025091.2; = p.T571I on NM_001090.3) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100400838; called by muse, mutect2, varscan2
- ABHD1 | c.756G>T p.Q252H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV99574503; called by muse, mutect2
- ABHD15 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.692); catalogued as rs752129442, COSV100212960; called by muse, mutect2, varscan2
- ABHD16B | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53863008; called by muse, mutect2, varscan2
- ABHD18 | c.409C>T p.R137* (on ENST00000398965 / NM_001039717.2; = p.R10* on NM_025097.2 and 10 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 34/64 reads (53%) | catalogued as rs1422365325, COSV66294741; called by muse, mutect2, varscan2
- ABHD18 | c.991G>T p.E331* (on ENST00000398965 / NM_001039717.2; = p.E238* on NM_025097.2 and 10 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as COSV101180741; called by muse, mutect2, varscan2
- ABHD2 | c.1147T>C p.S383P | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV100756277; called by muse, mutect2, varscan2
- ABHD8 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99917255; called by muse, mutect2, varscan2
- ABHD8 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.369); catalogued as rs190922068, COSV99917257; called by muse, varscan2
- ABI3BP | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201046479, COSV52532017; called by muse, mutect2, varscan2
- ABL1 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100583977; called by muse, mutect2, varscan2
- ABL2 | c.2121G>T p.Q707H (on ENST00000502732 / NM_007314.4; = p.Q692H on NM_005158.5) | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV100772712; called by muse, mutect2, varscan2
- ABL2 | c.982G>T p.E328* (on ENST00000502732 / NM_007314.4; = p.E313* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV100772713; called by muse, mutect2, varscan2
- ABL2 | c.337G>A p.V113I (on ENST00000502732 / NM_007314.4; = p.V98I on NM_005158.5) | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.479); catalogued as rs201168871, COSV100772715, COSV61018574; called by muse, mutect2, varscan2
- ABLIM3 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs145212062; called by muse, mutect2, varscan2
- ABLIM3 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs139404389; called by muse, mutect2, varscan2
- ABR | c.1640C>T p.A547V (on ENST00000302538 / NM_021962.5; = p.A510V on NM_001092.5) | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.105); catalogued as rs545589156, COSV52148238; called by muse, mutect2, varscan2
- ABR | c.737G>A p.S246N (on ENST00000302538 / NM_021962.5; = p.S209N on NM_001092.5) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV99347944; called by muse, mutect2, varscan2
- ABRA | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100357563; called by muse, mutect2, varscan2
- ABRAXAS2 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.781); catalogued as rs199511821, COSV53716573; called by muse, mutect2, varscan2
- ABTB1 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs748869280, COSV51740752; called by muse, mutect2, varscan2
- ABTB1 | c.992C>T p.T331I (on ENST00000232744 / NM_172027.3; = p.T189I on NM_032548.3) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs1248055838, COSV99229797; called by muse, varscan2
- AC004922.1 | c.1634G>A p.S545N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV99402924; called by muse, varscan2
- AC008676.3 | c.330G>T p.Q110H | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.773); catalogued as COSV100400413, COSV56638228; called by muse, mutect2, varscan2
- AC009779.3 | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV99221317; called by muse, mutect2, varscan2
- AC011455.2 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 57/143 reads (40%) | catalogued as COSV99671307; called by muse, mutect2, varscan2
- AC011462.1 | c.1085C>A p.A362D | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99524575; called by muse, mutect2, varscan2
- AC013489.1 | c.1155G>T p.E385D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99183862; called by muse, varscan2
- AC098582.1 | c.340G>T p.G114C | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99985594; called by muse, mutect2, varscan2
- AC098582.1 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as COSV99985596; called by muse, mutect2, varscan2
- AC126283.2 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758017357, CM099903, COSV101144430; called by muse, mutect2, varscan2
- AC253536.7 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs150924512; called by muse, varscan2
- ACACB | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs147821902; called by muse, mutect2, varscan2
- ACACB | c.3253G>A p.A1085T | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV100622875; called by muse, mutect2, varscan2
- ACAD11 | c.963G>T p.Q321H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99392034; called by muse, mutect2, varscan2
- ACAD9 | c.923G>A p.G308D | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100459202; called by muse, mutect2, varscan2
- ACADVL | c.480C>T p.Y160= | Splice Region (SNP) | VAF 53/127 reads (42%) | catalogued as rs371910495; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACAN | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100718074; called by muse, mutect2, varscan2
- ACAN | c.2279C>T p.T760I | Missense Mutation (SNP) | VAF 68/276 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100718077; called by muse, varscan2
- ACAN | c.4399C>A p.L1467I | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.99); PolyPhen benign (0.279); catalogued as rs368875483; called by muse, mutect2, varscan2
- ACCS | c.971A>G p.D324G | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV99772822; called by muse, mutect2, varscan2
- ACCSL | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV101122192, COSV66581010; called by muse, mutect2, varscan2
- ACCSL | c.564+2T>C p.X188_splice | Splice Site (SNP) | VAF 31/93 reads (33%) | catalogued as rs780860183, COSV101122193; called by muse, mutect2, varscan2
- ACE | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1439803774, COSV99329096; called by muse, mutect2, varscan2
- ACE | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1455284992, COSV99326282; called by muse, varscan2
- ACHE | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53816340, COSV99574090; called by muse, mutect2, varscan2
- ACIN1 | c.3800C>T p.A1267V | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as COSV52973592; called by muse, mutect2, varscan2
- ACIN1 | c.3427C>T p.R1143W | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs775004510, COSV99399595; called by muse, mutect2, varscan2
- ACIN1 | c.2372C>A p.P791H | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV99399598; called by muse, mutect2, varscan2
- ACKR2 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1420471671, COSV99825482; called by muse, mutect2, varscan2
- ACKR2 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs773144436, COSV99825525; called by muse, mutect2, varscan2
- ACKR3 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.336); catalogued as rs144999866; called by muse, mutect2, varscan2
- ACKR4 | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99392030; called by muse, mutect2, varscan2
- ACLY | c.2095G>A p.D699N | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV100709691; called by muse, mutect2, varscan2
- ACO2 | c.1024C>T p.L342F | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99347389; called by muse, varscan2
- ACOT12 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100296915; called by muse, mutect2, varscan2
- ACOX3 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as rs753581748, COSV100711950; called by muse, mutect2, varscan2
- ACOXL | c.546G>A p.E182= | Splice Region (SNP) | VAF 34/80 reads (43%) | catalogued as COSV100490200; called by muse, mutect2, varscan2
- ACR | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376947740; called by muse, mutect2, varscan2
- ACR | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs1464574890, COSV99334434; called by mutect2, varscan2
- ACSM1 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs61743525, COSV54641831; called by muse, mutect2, varscan2
- ACSM1 | c.849G>T p.W283C | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99532966; called by muse, mutect2, varscan2
- ACSM2A | c.1157C>T p.A386V (on ENST00000219054; = p.A307V on NM_001308169.2) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as COSV99525230; called by muse, mutect2, varscan2
- ACSM2A | c.1629G>T p.K543N (on ENST00000219054; = p.K464N on NM_001308169.2) | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54582113, COSV99525233; called by muse, mutect2, varscan2
- ACSS1 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs754529166, COSV60220623; called by muse, mutect2, varscan2
- ACSS2 | c.837C>A p.I279= | Splice Region (SNP) | VAF 59/132 reads (45%) | catalogued as COSV99489841; called by muse, mutect2, varscan2
- ACTB | c.589G>A p.G197S | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as rs1554329317, COSV100079626; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTBL2 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 41/91 reads (45%) | catalogued as rs954378153, COSV70660955, COSV70661840; called by muse, mutect2, varscan2
- ACTG2 | c.514C>A p.L172M | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV100609177; called by muse, varscan2
- ACTL6A | c.295T>G p.F99V | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV101199671; called by muse, mutect2, varscan2
- ACTL6B | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.941); catalogued as COSV99355570; called by muse, mutect2, varscan2
- ACTN3 | c.2254C>T p.R752* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | catalogued as rs763208690, COSV100074264, COSV100074529; called by muse, mutect2, varscan2
- ACTN4 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as rs752211925, COSV53143841; called by muse, mutect2, varscan2
- ACTR1A | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs1360371362, COSV64023074; called by muse, mutect2, varscan2
- ACTR3B | c.1022G>A p.R341K | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.05); catalogued as COSV99754041; called by muse, mutect2, varscan2
- ACTRT1 | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64419626; called by muse, mutect2, varscan2
- ACVR1B | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99231488; called by muse, mutect2, varscan2
- ACVR1C | c.1211G>T p.R404M | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99694684; called by muse, mutect2, varscan2
- ADAD1 | c.1276G>T p.G426C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99635635; called by muse, mutect2, varscan2
- ADAM11 | c.1123G>T p.G375* | Nonsense Mutation (SNP) | VAF 27/67 reads (40%) | catalogued as COSV99567461; called by muse, mutect2, varscan2
- ADAM11 | c.1430G>A p.C477Y | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99567462; called by muse, varscan2
- ADAM15 | c.2212G>T p.A738S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV99664994; called by muse, mutect2, varscan2
- ADAM17 | c.1922G>A p.C641Y | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100176258; called by muse, mutect2, varscan2
- ADAM20 | c.1520C>T p.T507M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs188347579, COSV99833430; called by muse, mutect2, varscan2
- ADAM28 | c.1064A>C p.K355T | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.856); catalogued as COSV99738658; called by muse, mutect2, varscan2
- ADAM32 | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 20/36 reads (56%) | catalogued as COSV65948949; called by muse, varscan2
- ADAM8 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.063); catalogued as rs756639059, COSV101291663; called by muse, varscan2
- ADAMTS13 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs782214086, COSV100747079; called by muse, mutect2, varscan2
- ADAMTS17 | c.2571C>A p.N857K | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99170667; called by muse, mutect2, varscan2
- ADAMTS2 | c.3121G>A p.V1041I | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs778184902, COSV52381127; called by muse, mutect2, varscan2
- ADAMTS2 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV99201001; called by muse, mutect2
- ADAMTS20 | c.5112T>G p.C1704W | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101239297; called by muse, mutect2, varscan2
- ADAMTS20 | c.2335C>T p.L779F | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV101166252; called by muse, mutect2, varscan2
- ADAMTS3 | c.3158G>A p.R1053H | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.932); catalogued as rs370314161; called by muse, mutect2, varscan2
- ADAMTS3 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs373312832, COSV54387019; called by muse, mutect2, varscan2
- ADAMTS3 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs1185511556, COSV99711063, COSV99712380; called by muse, mutect2, varscan2
- ADAMTS5 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs371256284; called by muse, mutect2
- ADAMTS7 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs777140162, COSV101183103; called by muse, mutect2, varscan2
- ADAMTS9 | c.3814G>A p.V1272M | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as rs1478846671, COSV55782364; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2809C>T p.R937* | Nonsense Mutation (SNP) | VAF 31/86 reads (36%) | catalogued as rs370313572; called by muse, mutect2, varscan2
- ADAMTSL4 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99647300; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs587737331, COSV55008180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs754966903, CM159909, COSV99647304; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2951G>A p.R984H | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs200667760; called by muse, mutect2, varscan2
- ADAP2 | c.702G>T p.Q234H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100437243; called by muse, mutect2, varscan2
- ADAR | c.2861C>A p.T954N | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.76); PolyPhen benign (0.197); catalogued as COSV99425982; called by muse, mutect2, varscan2
- ADAR | c.2216G>A p.G739D | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99425986; called by muse, mutect2, varscan2
- ADAR | c.1799A>G p.Q600R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.202); catalogued as COSV99425987; called by muse, mutect2, varscan2
- ADARB1 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as rs779755980, COSV100653818; called by muse, mutect2, varscan2
- ADARB1 | c.1648C>T p.R550W (on ENST00000360697 / NM_001346687.2; = p.R510W on NM_001112.4) | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62348097; called by muse, mutect2, varscan2
- ADARB1 | c.1796C>T p.A599V (on ENST00000360697 / NM_001346687.2; = p.A559V on NM_001112.4) | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.996); catalogued as rs779673374, COSV100653824, COSV62343731; called by muse, mutect2, varscan2
- ADARB2 | c.1969C>T p.R657W | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs201838719, COSV67182577; called by muse, mutect2, varscan2
- ADARB2 | c.1819G>A p.G607S | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.75); catalogued as rs920253622, COSV101184553, COSV67181854; called by muse, mutect2, varscan2
- ADARB2 | c.1384C>T p.R462* | Nonsense Mutation (SNP) | VAF 29/70 reads (41%) | catalogued as COSV101186898; called by muse, mutect2, varscan2
- ADAT2 | c.247T>C p.W83R | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.986); catalogued as COSV99395771; called by muse, mutect2, varscan2
- ADCK1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99451706; called by muse, mutect2, varscan2
- ADCK1 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs763294475, COSV99451711; called by muse, mutect2
- ADCK1 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.078); catalogued as rs141695743; called by muse, mutect2, varscan2
- ADCK2 | c.1293G>A p.M431I | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV99301618; called by muse, mutect2, varscan2
- ADCY1 | c.1069G>A p.V357M | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52031540; called by muse, mutect2, varscan2
- ADCY10 | c.4034G>A p.C1345Y | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs748895833, COSV100896844; called by muse, mutect2, varscan2
- ADCY10 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.055); catalogued as COSV100896845; called by muse, mutect2, varscan2
- ADCY3 | c.3122G>A p.R1041H | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750100320, COSV99568242; called by muse, mutect2, varscan2
- ADCY7 | c.1166A>T p.K389M | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99575993; called by muse, mutect2, varscan2
- ADCY9 | c.1310A>C p.K437T | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99569995; called by muse, mutect2, varscan2
- ADCYAP1 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs772983512, COSV99036150, COSV99327513; called by muse, mutect2, varscan2
- ADGRA1 | c.1344G>A p.W448* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as COSV100811022; called by muse, mutect2, varscan2
- ADGRA2 | c.3032G>A p.S1011N | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99604918; called by muse, mutect2, varscan2
- ADGRA2 | c.3136C>T p.P1046S | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.8); PolyPhen benign (0.09); catalogued as COSV99604921; called by muse, mutect2, varscan2
- ADGRA3 | c.994A>G p.N332D | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV99293277; called by muse, mutect2, varscan2
- ADGRB1 | c.2436C>A p.F812L | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV60094381; called by muse, mutect2, varscan2
- ADGRB2 | c.3630G>T p.Q1210H | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV99926210; called by muse, mutect2, varscan2
- ADGRB2 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV99926216, COSV99926885; called by muse, mutect2, varscan2
- ADGRB3 | c.1930-1G>A p.X644_splice | Splice Site (SNP) | VAF 5/21 reads (24%) | catalogued as COSV101000701; called by muse, mutect2
- ADGRD1 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as rs369201469, COSV99895406; called by muse, mutect2, varscan2
- ADGRE1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs149695793; called by muse, mutect2, varscan2
- ADGRF1 | c.597G>T p.Q199H | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99347262; called by muse, mutect2, varscan2
- ADGRF1 | c.453G>A p.K151= | Splice Region (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99347263; called by muse, mutect2, varscan2
- ADGRG2 | c.2194C>T p.R732* (on ENST00000379869 / NM_001079858.3; = p.R729* on NM_005756.4) | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | catalogued as COSV100491988, COSV100492254; called by muse, mutect2, varscan2
- ADGRG4 | c.179A>G p.D60G | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99795442; called by muse, mutect2, varscan2
- ADGRG4 | c.2039A>C p.E680A | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV99795444; called by muse, mutect2, varscan2
- ADGRG4 | c.6521C>T p.T2174I | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as COSV99795446; called by muse, mutect2, varscan2
- ADGRG4 | c.7721C>T p.T2574M | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.608); catalogued as COSV54961592; called by muse, mutect2, varscan2
- ADGRG6 | c.1685A>G p.Y562C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV99747136; called by muse, mutect2, varscan2
- ADGRG7 | c.893G>A p.G298D | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99841026; called by muse, mutect2, varscan2
- ADGRL1 | c.3880C>T p.R1294W (on ENST00000340736 / NM_001008701.3; = p.R1289W on NM_014921.5) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746407235, COSV100529547, COSV61565126; called by muse, mutect2, varscan2
- ADGRV1 | c.4832C>T p.T1611I | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.733); catalogued as COSV101315936; called by muse, mutect2, varscan2
- ADH4 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as rs1465972449, COSV55501076; called by muse, mutect2, varscan2
- ADH7 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1254796684, COSV52922879, COSV99265238; called by muse, mutect2, varscan2
- ADHFE1 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99397836; called by muse, mutect2, varscan2
- ADIPOQ | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV100292164; called by muse, mutect2, varscan2
- ADIPOR1 | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV100579525; called by muse, mutect2, varscan2
- ADNP2 | c.3118G>A p.A1040T | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV100080848; called by muse, mutect2, varscan2
- ADORA1 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99704528; called by muse, mutect2, varscan2
- ADORA3 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV99598732; called by muse, mutect2, varscan2
- ADPRH | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100813314; called by muse, mutect2, varscan2
- ADPRS | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs201025691, COSV99255514; called by muse, mutect2, varscan2
- ADRB3 | c.1039T>G p.C347G | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100799895; called by muse, mutect2
- ADTRP | c.440A>G p.H147R | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.183); catalogued as COSV99995286; called by muse, mutect2, varscan2
- AEBP1 | c.321G>T p.K107N | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV56262562; called by muse, mutect2, varscan2
- AEN | c.359C>T p.T120M | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs766037818, COSV60430036; called by muse, mutect2, varscan2
- AFAP1 | c.1875G>T p.K625N | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.287); catalogued as COSV100631504, COSV61793694; called by muse, mutect2, varscan2
- AFAP1L1 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs781501981, COSV57046630, COSV99695897; called by muse, mutect2, varscan2
- AFAP1L2 | c.949G>A p.V317I | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100412535; called by muse, mutect2, varscan2
- AFDN | c.5342G>A p.G1781E (on ENST00000447894 / NM_001366320.1; = p.G1700E on NM_001207008.1) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.163); catalogued as COSV100652837, COSV100652981; called by muse, mutect2, varscan2
- AFF1 | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV100320580; called by muse, mutect2, varscan2
- AFF2 | c.1690C>A p.Q564K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.523); catalogued as COSV99663909; called by muse, mutect2, varscan2
- AFF2 | c.2642C>T p.P881L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99663913; called by muse, mutect2, varscan2
- AGAP2 | c.2375C>T p.T792I (on ENST00000547588 / NM_001122772.2; = p.T456I on NM_014770.4) | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs754172447, COSV99223154; called by muse, mutect2, varscan2
- AGBL1 | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759855721, COSV101223059, COSV101224133; called by muse, mutect2, varscan2
- AGBL2 | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV100101687; called by muse, mutect2, varscan2
- AGBL2 | c.2414del p.L805Yfs*3 | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | catalogued as COSV104405789; called by mutect2, pindel, varscan2
- AGBL2 | c.572A>G p.N191S | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV100101690; called by muse, varscan2
- AGBL5 | c.2117A>G p.Q706R | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs776394116, COSV64080348; called by muse, mutect2, varscan2
- AGL | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200180652, COSV54054144; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGMAT | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs549021034, COSV65436132; called by muse, mutect2, varscan2
- AGO2 | c.1806del p.A603Pfs*92 | Frame Shift Del (DEL) | VAF 24/54 reads (44%) | catalogued as rs748399150; called by mutect2, varscan2
- AGO2 | c.817G>T p.G273W | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99595721; called by muse, mutect2, varscan2
- AGO4 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1236395746, COSV64616893; called by muse, mutect2, varscan2
- AGPAT4 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs773798140, COSV57245566; called by muse, mutect2, varscan2
- AGPS | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.285); catalogued as COSV99931299; called by muse, mutect2, varscan2
- AGR2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.227); catalogued as rs1433204717, COSV68596348; called by muse, mutect2, varscan2
- AGR2 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV68596585, COSV68597468; called by muse, mutect2, varscan2
- AGRN | c.4513G>A p.V1505M | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as rs372918766; ClinVar: uncertain significance; called by muse, varscan2
- AGTR1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs995803867, COSV62557611; called by muse, mutect2, varscan2
- AGXT | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs1002762120, COSV100280073; called by muse, mutect2, varscan2
- AHCY | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as rs199533546, COSV54152885; called by muse, mutect2, varscan2
- AHDC1 | c.4564G>A p.A1522T | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as COSV99899286; called by muse, mutect2, varscan2
- AHDC1 | c.2020G>A p.G674S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.985); catalogued as rs369141457; called by muse, mutect2, varscan2
- AHNAK | c.11442G>A p.M3814I | Missense Mutation (SNP) | VAF 94/220 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.208); catalogued as COSV99947411; called by muse, mutect2, varscan2
- AHNAK | c.8558T>C p.V2853A | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as COSV99947414; called by muse, mutect2, varscan2
- AHNAK | c.4288C>T p.P1430S | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.415); catalogued as COSV99945022; called by muse, mutect2, varscan2
- AHNAK | c.2966T>C p.M989T | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV99947418; called by muse, mutect2, varscan2
- AHNAK2 | c.14056T>G p.L4686V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV100317488; called by muse, mutect2, varscan2
- AHNAK2 | c.1028G>A p.G343D | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.057); catalogued as COSV60908281; called by muse, mutect2, varscan2
- AHR | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as rs533269895, COSV54121537, COSV99619757; called by muse, mutect2, varscan2
- AHRR | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs373499533; called by muse, mutect2, varscan2
- AIFM1 | c.1437G>T p.Q479H | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99781020; called by muse, mutect2, varscan2
- AIFM3 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs1315756262, COSV100104606; called by muse, mutect2, varscan2
- AIFM3 | c.1092G>T p.E364D | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.173); catalogued as COSV100104608; called by muse, mutect2, varscan2
- AIG1 | c.74A>G p.K25R | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.043); catalogued as COSV99263791; called by muse, mutect2, varscan2
- AJUBA | c.818G>A p.G273D | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV99400983; called by muse, mutect2, varscan2
- AK3 | c.139C>A p.L47M | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV100729465; called by muse, mutect2, varscan2
- AK5 | c.1235G>A p.R412H (on ENST00000354567 / NM_174858.3; = p.R386H on NM_012093.4) | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); catalogued as rs61746349, COSV60977905; called by muse, mutect2, varscan2
- AKAP12 | c.743G>T p.S248I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV99483191; called by muse, mutect2, varscan2
- AKAP12 | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99483193; called by muse, mutect2, varscan2
- AKAP12 | c.4495G>A p.D1499N | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV99483199; called by muse, mutect2, varscan2
- AKAP13 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146142499; called by muse, mutect2, varscan2
- AKAP14 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.127); catalogued as rs1433845368, COSV57629901; called by muse, mutect2, varscan2
- AKAP17A | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100002231; called by muse, mutect2, varscan2
- AKAP17A | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); catalogued as COSV100002234; called by muse, mutect2, varscan2
- AKAP3 | c.1691C>A p.P564H | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.386); catalogued as COSV99962129; called by muse, mutect2, varscan2
- AKAP4 | c.2267G>A p.G756E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100654261; called by muse, mutect2, varscan2
- AKAP9 | c.2323G>T p.A775S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.044); catalogued as rs1437671599, COSV100662380; called by muse, mutect2, varscan2
- AKR1C3 | c.938G>A p.S313N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV101003077; called by muse, mutect2, varscan2
- AL035461.3 | c.3001C>T p.R1001W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs753805913, COSV101125455; called by muse, mutect2, varscan2
- AL645922.1 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.11); catalogued as rs1395795972, COSV100191092; called by muse, mutect2, varscan2
- ALAD | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.422); catalogued as rs746212674, COSV99474765; called by muse, mutect2, varscan2
- ALAS1 | c.389T>A p.L130H | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as COSV100050327; called by muse, mutect2, varscan2
- ALAS2 | c.1265C>A p.S422Y | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100238284, COSV58193160; called by muse, mutect2, varscan2
- ALDH1B1 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV100890940; called by muse, mutect2, varscan2
- ALDH1L1 | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1266949739, COSV56415008; called by muse, mutect2, varscan2
- ALDH1L2 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs763371443, COSV51559408; called by muse, mutect2, varscan2
- ALDH3A2 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); catalogued as rs779945294, COSV51566168; called by muse, mutect2, varscan2
- ALDH7A1 | c.1568C>A p.T523N | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD1512350, COSV101302021; called by muse, mutect2, varscan2
- ALDOA | c.289C>T p.R97W (on ENST00000642816 / NM_001243177.4; = p.R43W on NM_184041.5) | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs757047929, COSV100582070; called by muse, mutect2, varscan2
- ALG13 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); catalogued as COSV99322195; called by muse, mutect2, varscan2
- ALG13 | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.001); catalogued as COSV99322204; called by muse, mutect2, varscan2
- ALG6 | c.1486G>A p.D496N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV99585912; called by muse, mutect2, varscan2
- ALKBH2 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as rs1339933873, COSV57448929; called by muse, mutect2, varscan2
- ALOX5AP | c.241+1G>A p.X81_splice | Splice Site (SNP) | VAF 33/71 reads (46%) | catalogued as COSV100996286; called by muse, mutect2, varscan2
- ALPK1 | c.1856C>A p.T619N | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.296); catalogued as COSV99454082; called by muse, mutect2, varscan2
- ALPK2 | c.3562G>T p.G1188C | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV100864386; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- ALPK2 | c.787A>G p.N263D | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100864387; called by muse, mutect2
- ALPL | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as rs762216748, COSV100876227; called by muse, mutect2, varscan2
- ALS2 | c.3032T>C p.M1011T | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99969273; called by muse, mutect2, varscan2
- ALS2CL | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs554056115, COSV100015035, COSV59674084; called by muse, mutect2, varscan2
- ALX3 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs535409677, COSV100873880, COSV63928852; called by muse, mutect2, varscan2
- AMBRA1 | c.1039G>A p.E347K (on ENST00000458649 / NM_001367468.1; = p.E257K on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs1389326926, COSV54055813; called by muse, mutect2, varscan2
- AMDHD2 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99565835; called by muse, mutect2, varscan2
- AMER1 | c.1814G>T p.G605V | Missense Mutation (SNP) | VAF 90/216 reads (42%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs957383245, COSV100366097, COSV57655763; called by muse, mutect2, varscan2
- AMER3 | c.2480C>T p.A827V | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV100366528; called by muse, varscan2
- AMIGO3 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.44); catalogued as COSV100246577; called by muse, mutect2, varscan2
- AMN1 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs889986563, COSV55671992; called by muse, mutect2, varscan2
- AMOT | c.2654C>T p.A885V (on ENST00000371959 / NM_001113490.1; = p.A476V on NM_133265.3) | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV100495048; called by muse, mutect2, varscan2
- AMOTL1 | c.2272C>A p.L758I | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1486932137, COSV100504389; called by muse, mutect2, varscan2
- AMPD3 | c.2128-1G>T p.X710_splice (on ENST00000396553 / NM_001025389.2; = p.X719_splice on NM_000480.3) | Splice Site (SNP) | VAF 17/38 reads (45%) | catalogued as COSV101158170; called by muse, varscan2
- AMY2B | c.386C>T p.T129I | Missense Mutation (SNP) | VAF 89/303 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.265); catalogued as COSV100796199; called by muse, varscan2
- AMY2B | c.812T>C p.F271S | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100796300; called by muse, mutect2, varscan2
- AMY2B | c.1040C>A p.P347H | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100796301, COSV63716716, COSV63716753; called by muse, mutect2, varscan2
- AMZ1 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs376694807, COSV56685496; called by muse, mutect2, varscan2
- AMZ1 | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100406386; called by muse, mutect2, varscan2
- ANAPC1 | c.5368T>C p.Y1790H | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.092); catalogued as COSV100594716; called by muse, mutect2, varscan2
- ANAPC1 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 34/63 reads (54%) | catalogued as COSV100594719; called by muse, mutect2, varscan2
- ANAPC2 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 95/222 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as rs1291251076, COSV60570858; called by muse, mutect2, varscan2
- ANAPC2 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.719); catalogued as rs766767193, COSV59244858; called by muse, mutect2, varscan2
- ANAPC4 | c.745A>T p.T249S | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.084); catalogued as COSV100193997; called by muse, mutect2, varscan2
- ANG | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as rs746187039, COSV100390918; called by muse, mutect2, varscan2
- ANGEL2 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs190621865, COSV100853948; called by muse, mutect2, varscan2
- ANGPT4 | c.1373G>A p.G458D | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101124728; called by muse, mutect2, varscan2
- ANK1 | c.4698G>C p.M1566I | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); catalogued as COSV99225214; called by muse, mutect2, varscan2
- ANK1 | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs772536407, COSV55884253; called by muse, mutect2, varscan2
- ANK2 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759136608, COSV100001604; called by muse, mutect2, varscan2
- ANK3 | c.12420del p.K4140Nfs*15 (on ENST00000280772 / NM_001320874.2; = p.K661Nfs*15 on NM_001149.3) | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | catalogued as rs1466658148; called by mutect2, pindel, varscan2
- ANK3 | c.5252C>T p.S1751F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as rs769637500, COSV99779920; called by muse, mutect2, varscan2
- ANK3 | c.3511C>A p.L1171I (on ENST00000280772 / NM_001320874.2; = p.L305I on NM_001149.3) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55072667, COSV99779922; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5462C>T p.T1821M | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.374); catalogued as rs776994725, COSV99783298; called by muse, mutect2, varscan2
- ANKRD12 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as rs1399264475, COSV100041315; called by muse, mutect2, varscan2
- ANKRD13A | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs142252344; called by muse, mutect2, varscan2
- ANKRD13B | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as COSV61471198; called by muse, mutect2, varscan2
- ANKRD17 | c.2992C>A p.L998M | Missense Mutation (SNP) | VAF 77/152 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); catalogued as COSV100429196; called by muse, mutect2, varscan2
- ANKRD24 | c.3238G>A p.A1080T | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as rs376946018, COSV99517486; called by muse, mutect2, varscan2
- ANKRD28 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV101080649; called by muse, mutect2, varscan2
- ANKRD33 | c.38C>T p.A13V (on ENST00000340970 / NM_001304459.2; = p.A148V on NM_182608.4) | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV56607455; called by muse, mutect2
- ANKRD34A | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100041246; called by muse, mutect2, varscan2
- ANKRD36 | c.233C>A p.P78Q | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV101347381; called by muse, varscan2
- ANKRD36 | c.299C>T p.T100I | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV101347382; called by muse, varscan2
- ANKRD37 | c.364A>G p.M122V | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs772390105, COSV99249091; called by muse, mutect2, varscan2
- ANKRD39 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.061); catalogued as rs11556450, COSV101135635, COSV66813182; called by muse, mutect2, varscan2
- ANKRD46 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | catalogued as COSV59515362; called by muse, mutect2, varscan2
- ANKRD46 | c.55G>C p.A19P | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV100170044; called by muse, mutect2, varscan2
- ANKRD50 | c.1207A>C p.T403P | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as COSV101538958; called by muse, mutect2, varscan2
- ANKS1B | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV61335084, COSV61338267; called by mutect2, varscan2
- ANKS6 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs781295888, COSV62051247; called by muse, mutect2, varscan2
- ANKZF1 | c.558+2C>T p.X186_splice | Splice Site (SNP) | VAF 16/52 reads (31%) | catalogued as COSV99850524; called by muse, mutect2, varscan2
- ANLN | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99732288; called by muse, mutect2, varscan2
- ANO1 | c.2764C>T p.Q922* | Nonsense Mutation (SNP) | VAF 57/123 reads (46%) | catalogued as COSV100797068; called by muse, mutect2, varscan2
- ANO2 | c.2389G>A p.G797R (on ENST00000356134 / NM_001278597.3; = p.G801R on NM_001278596.3) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs774552828, COSV59049454; called by muse, mutect2, varscan2
- ANP32B | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as COSV100233247; called by muse, mutect2, varscan2
- ANPEP | c.2710G>A p.A904T | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.297); catalogued as COSV100263053; called by muse, mutect2, varscan2
- ANTXR2 | c.1055C>A p.P352H | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100226535; called by muse, mutect2, varscan2
- ANXA13 | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV99146118; called by muse, mutect2, varscan2
- ANXA3 | c.685A>C p.K229Q | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV99363712; called by muse, mutect2, varscan2
- ANXA3 | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99363714; called by muse, varscan2
- AOC1 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs766971033, COSV62868602, COSV62870832; called by muse, mutect2, varscan2
- AOC3 | c.1363C>A p.L455I | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV99520147; called by muse, mutect2, varscan2
- AOX1 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); catalogued as rs368293055, COSV65981353; called by muse, mutect2, varscan2
- AP002748.5 | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 70/154 reads (45%) | catalogued as rs745656125, CM031137, COSV100567924; called by muse, mutect2, varscan2
- AP1B1 | c.1795T>A p.S599T | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.984); catalogued as COSV100434587; called by muse, mutect2, varscan2
- AP1B1 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766149155, COSV58017873; called by muse, mutect2, varscan2
- AP1G1 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV100250417; called by muse, mutect2, varscan2
- AP1M1 | c.314A>G p.D105G | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99358379; called by muse, mutect2, varscan2
- AP1M2 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs549899023, COSV51565339; called by muse, mutect2, varscan2
- AP2A1 | c.1741G>A p.V581M | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.482); catalogued as COSV100756170, COSV62820011; called by muse, mutect2, varscan2
- AP2A2 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs768056290, COSV59962025; called by muse, mutect2, varscan2
- AP3B1 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868382649, COSV99671346; called by muse, mutect2, varscan2
- AP3B2 | c.2336C>T p.S779F | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV99916487; called by muse, mutect2, varscan2
- AP5B1 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.727); catalogued as rs766354109, COSV100376006; called by muse, mutect2, varscan2
- AP5Z1 | c.2117C>T p.T706M | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs752688603, COSV100804123; called by muse, mutect2, varscan2
- APBA1 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV99596061; called by muse, mutect2, varscan2
- APBB3 | c.1400G>A p.R467Q (on ENST00000357560 / NM_133173.2; = p.R474Q on NM_006051.3) | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs773944900, COSV60366370; called by muse, mutect2, varscan2
- APC2 | c.5113G>A p.A1705T | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV99279436; called by muse, mutect2, varscan2
- APEH | c.792G>A p.W264* | Nonsense Mutation (SNP) | VAF 96/205 reads (47%) | catalogued as COSV99610770; called by muse, mutect2, varscan2
- APEX2 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV100238278; called by muse, mutect2, varscan2
- APEX2 | c.1330G>T p.E444* | Nonsense Mutation (SNP) | VAF 36/89 reads (40%) | catalogued as COSV100238280; called by muse, mutect2, varscan2
- APLP1 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs761017755, COSV55703195, COSV55707221; called by muse, mutect2, varscan2
- APMAP | c.884A>G p.D295G | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV99468583; called by muse, varscan2
- APMAP | c.425C>T p.T142I | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.231); catalogued as rs1568812480, COSV99468589; called by muse, mutect2, varscan2
- APOBEC2 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs202202906, COSV99775372; called by muse, mutect2
- APOBEC2 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.618); catalogued as rs748696871, COSV55143998; called by muse, mutect2, varscan2
- APOBEC3B | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as rs772607602, COSV100213765; called by muse, mutect2, varscan2
- APOBEC3F | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs549076724, COSV57910733; called by muse, mutect2, varscan2
- APOBEC3G | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 38/67 reads (57%) | catalogued as rs779756048, COSV101349075; called by muse, mutect2, varscan2
- APOBEC3G | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as rs780901950, COSV101349076, COSV68470704; called by muse, mutect2, varscan2
- APOL5 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99968392; called by muse, mutect2, varscan2
- APOL6 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs537732644, COSV101290982; called by muse, mutect2, varscan2
- APOM | c.203A>G p.N68S | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as rs1223222648, COSV99277005; called by muse, mutect2, varscan2
- AQP1 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as rs745651824, CD1213105, COSV61267649; called by muse, mutect2, varscan2
- ARAP1 | c.3952C>T p.R1318W (on ENST00000393609 / NM_001040118.2; = p.R1073W on NM_015242.4) | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV100501903; called by muse, mutect2, varscan2
- ARAP1 | c.2420C>A p.P807H (on ENST00000393609 / NM_001040118.2; = p.P562H on NM_015242.4) | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100501905; called by muse, mutect2, varscan2
- ARAP2 | c.3944C>T p.T1315I | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV58285980; called by muse, mutect2, varscan2
- ARAP2 | c.494C>A p.S165Y | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as rs1028691433, COSV100394650; called by muse, mutect2
- ARFGEF1 | c.357T>A p.S119R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV99142332; called by muse, mutect2, varscan2
- ARFGEF2 | c.2554C>T p.R852W | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1335667047, COSV64212614; called by muse, mutect2, varscan2
- ARFGEF3 | c.2648G>A p.R883Q | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.859); catalogued as rs747544365, COSV52450223; called by muse, mutect2, varscan2
- ARHGAP10 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs756616736, COSV60595224; called by muse, mutect2, varscan2
- ARHGAP10 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100331227; called by muse, mutect2, varscan2
- ARHGAP10 | c.2254G>A p.G752R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100331228; called by muse, mutect2, varscan2
- ARHGAP11A | c.866T>C p.F289S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100853242; called by muse, mutect2, varscan2
- ARHGAP11A | c.1894C>T p.P632S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs771047764, COSV100853244; called by muse, mutect2, varscan2
- ARHGAP12 | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100260593; called by muse, mutect2, varscan2
- ARHGAP18 | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100936168; called by muse, mutect2, varscan2
- ARHGAP20 | c.638C>A p.T213N | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99504011; called by muse, mutect2, varscan2
- ARHGAP21 | c.4549C>A p.L1517I | Missense Mutation (SNP) | VAF 108/250 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.419); catalogued as COSV100256205; called by muse, varscan2
- ARHGAP21 | c.32A>G p.E11G | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.492); catalogued as rs767912407, COSV100903637; called by muse, varscan2
- ARHGAP24 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as rs754847297, COSV101232742; called by muse, mutect2
- ARHGAP24 | c.2104C>T p.R702* (on ENST00000395184 / NM_001025616.3; = p.R609* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as rs376118883; called by muse, mutect2, varscan2
- ARHGAP26 | c.100A>T p.K34* | Nonsense Mutation (SNP) | VAF 27/60 reads (45%) | catalogued as COSV99190930; called by muse, mutect2, varscan2
- ARHGAP27 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); catalogued as COSV99298995; called by muse, mutect2, varscan2
- ARHGAP28 | c.1781C>T p.T594M (on ENST00000383472 / NM_001366230.1; = p.T435M on NM_001010000.3) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs144213417, COSV51638114; called by muse, mutect2, varscan2
- ARHGAP29 | c.1810A>G p.T604A | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.074); catalogued as COSV99558160; called by muse, mutect2, varscan2
- ARHGAP31 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as rs749661211, COSV51791883; called by muse, mutect2, varscan2
- ARHGAP31 | c.1442G>A p.R481H | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs1334865793, COSV51798428; called by muse, varscan2
- ARHGAP31 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV51795140; called by muse, varscan2
- ARHGAP33 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 42/82 reads (51%) | catalogued as COSV99138275; called by muse, mutect2, varscan2
- ARHGAP33 | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs763204420, COSV50155165; called by muse, mutect2, varscan2
- ARHGAP35 | c.4255C>T p.R1419C | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768711914, COSV68330192; called by muse, mutect2, varscan2
- ARHGAP39 | c.1969C>A p.L657I | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV99431272; called by muse, mutect2, varscan2
- ARHGAP39 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52768235; called by muse, mutect2
- ARHGAP44 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770270968, COSV99310673; called by muse, mutect2, varscan2
- ARHGAP44 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99310676; called by muse, mutect2, varscan2
- ARHGAP45 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs760322013, COSV99565766; called by muse, mutect2, varscan2
- ARHGAP45 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as COSV100490687; called by muse, mutect2, varscan2
- ARHGAP45 | c.1018T>C p.Y340H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV57428603; called by muse, mutect2, varscan2
- ARHGAP6 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV100272824; called by muse, mutect2, varscan2
- ARHGAP8 | c.763+2T>C p.X255_splice (on ENST00000389774 / NM_001017526.1; = p.X224_splice on NM_181335.3) | Splice Site (SNP) | VAF 53/110 reads (48%) | catalogued as COSV100424247; called by muse, mutect2, varscan2
- ARHGDIB | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs773817916, COSV57455656; called by muse, varscan2
- ARHGEF10 | c.773A>G p.D258G (on ENST00000398564; = p.D233G on NM_014629.4) | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100034497; called by muse, mutect2, varscan2
- ARHGEF10 | c.1277T>C p.L426P (on ENST00000398564; = p.L401P on NM_014629.4) | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100034501; called by muse, mutect2, varscan2
- ARHGEF10 | c.3992C>T p.A1331V (on ENST00000398564; = p.A1306V on NM_014629.4) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375455536; called by muse, mutect2, varscan2
- ARHGEF10L | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs776139457, COSV63423088; called by muse, mutect2, varscan2
- ARHGEF12 | c.2854G>T p.E952* | Nonsense Mutation (SNP) | VAF 23/38 reads (61%) | catalogued as COSV100754915, COSV100755034; called by muse, mutect2, varscan2
- ARHGEF15 | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100730044; called by muse, mutect2
- ARHGEF16 | c.1111T>C p.F371L | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV101000431; called by muse, mutect2
- ARHGEF17 | c.5074C>T p.P1692S | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs775376327, COSV99735615; called by muse, mutect2, varscan2
- ARHGEF19 | c.2270G>A p.R757H | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368259205; called by muse, mutect2, varscan2
- ARHGEF26 | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.968); catalogued as COSV100726553; called by muse, mutect2, varscan2
- ARHGEF26 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 70/86 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV62845345; called by muse, varscan2
- ARHGEF26 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV62847241; called by muse, varscan2
- ARHGEF35 | c.1285G>A p.V429M | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs553072768, COSV100967808; called by muse, mutect2
- ARHGEF4 | c.899T>G p.I300S | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100388099; called by muse, mutect2, varscan2
- ARHGEF4 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs773406931, COSV100388111; called by muse, mutect2, varscan2
- ARHGEF40 | c.4033C>T p.R1345C | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1380053775, COSV100070329; called by muse, mutect2, varscan2
- ARHGEF5 | c.3571C>T p.R1191C | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs560154773, COSV50209634; called by muse, mutect2, varscan2
- ARHGEF6 | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1266145678, COSV99166463; called by muse, mutect2, varscan2
- ARHGEF7 | c.2132C>A p.A711D (on ENST00000375741 / NM_001113511.2; = p.A533D on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99521516; called by muse, varscan2
- ARID1A | c.1650dup p.Y551Lfs*72 | Frame Shift Ins (INS) | VAF 33/86 reads (38%) | catalogued as rs1415146710; called by mutect2, pindel, varscan2
- ARID1B | c.1805G>A p.S602N | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763818779, COSV99269069; called by muse, mutect2, varscan2
- ARID1B | c.4475G>T p.R1492M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.31); catalogued as COSV99269070; called by muse, mutect2, varscan2
- ARID2 | c.2398C>T p.H800Y | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as COSV100536179; called by muse, mutect2, varscan2
- ARID3B | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV100654633; called by muse, mutect2, varscan2
- ARID4A | c.2310G>T p.Q770H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV100794239; called by muse, mutect2, varscan2
- ARID4B | c.3365C>A p.A1122D | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV99935611; called by muse, mutect2, varscan2
- ARID4B | c.2867C>T p.P956L | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.992); catalogued as rs752314679, COSV99935612; called by muse, mutect2, varscan2
- ARID5B | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99689662; called by muse, mutect2, varscan2
- ARID5B | c.1945C>T p.L649F | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.371); catalogued as COSV99689668; called by muse, mutect2, varscan2
- ARL5A | c.293G>T p.R98M | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99706630; called by muse, mutect2, varscan2
- ARL5B | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as COSV66011148; called by muse, mutect2, varscan2
- ARL6IP5 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs11542221, COSV56234277; called by muse, mutect2, varscan2
- ARMC3 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.744); catalogued as rs1334966869, COSV99958064; called by muse, mutect2
- ARMC3 | c.2393G>A p.R798Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372574174; called by muse, mutect2, varscan2
- ARMC4 | c.3094C>T p.R1032C | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745364784, COSV59460629; called by muse, mutect2, varscan2
- ARMC4 | c.2896G>A p.A966T | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.74); catalogued as COSV100536802; called by muse, mutect2, varscan2
- ARMC4 | c.1495C>A p.L499M | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV100536804; called by muse, mutect2, varscan2
- ARMC5 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM149023, COSV51655516, COSV51660203; called by muse, mutect2, varscan2
- ARMC5 | c.1370G>T p.R457M | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99192537; called by muse, mutect2, varscan2
- ARMC5 | c.2017C>T p.R673W | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs754756157, COSV99192538; called by muse, mutect2, varscan2
- ARMC9 | c.348G>A p.P116= | Splice Region (SNP) | VAF 52/117 reads (44%) | catalogued as rs751616290, COSV100589708, COSV63020329; called by muse, mutect2, varscan2
- ARMCX2 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs782665063, COSV57529938; called by muse, mutect2, varscan2
- ARMCX2 | c.647A>C p.E216A | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.045); catalogued as COSV100168155; called by muse, mutect2, varscan2
- ARMCX3 | c.359C>A p.P120H | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs375844900, COSV100362258; called by muse, mutect2, varscan2
- ARMH3 | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as COSV100898931; called by muse, mutect2, varscan2
- ARMH3 | c.508-1G>A p.X170_splice | Splice Site (SNP) | VAF 40/83 reads (48%) | catalogued as rs1047652191, COSV100898933; called by muse, mutect2, varscan2
- ARNT2 | c.1189C>A p.L397M | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.41); catalogued as COSV100309004; called by muse, mutect2, varscan2
- ARNTL2 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99667763; called by muse, mutect2, varscan2
- ARNTL2 | c.1586G>T p.R529M | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99667765; called by muse, mutect2, varscan2
- ARPC2 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV99826698; called by muse, mutect2, varscan2
- ARPP19 | c.169-1G>A p.X57_splice | Splice Site (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99992921; called by muse, mutect2, varscan2
- ARPP21 | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as rs749154477, COSV51796342; called by muse, mutect2, varscan2
- ARPP21 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs1478885794, COSV51791322; called by muse, mutect2, varscan2
- ARRB2 | c.758C>A p.P253H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.92); catalogued as COSV99347056; called by muse, mutect2, varscan2
- ARRDC4 | c.1103C>A p.P368H | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV99164371; called by muse, mutect2
- ARSA | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99332380; called by muse, mutect2, varscan2
- ARSB | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV99364756; called by muse, mutect2, varscan2
- ARSF | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100839499, COSV100839501; called by muse, mutect2, varscan2
- ARSF | c.1288A>G p.M430V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as COSV100839502; called by muse, varscan2
- ARSF | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV100839503; called by muse, varscan2
- ARSI | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV100155976; called by muse, mutect2, varscan2
- ARSJ | c.1555C>A p.L519I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100192697; called by muse, mutect2, varscan2
- ARSK | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101187543; called by muse, mutect2, varscan2
- ARSK | c.1093C>A p.L365I | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV101187544; called by muse, mutect2, varscan2
- ART1 | c.813G>T p.K271N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.658); catalogued as COSV99167165; called by muse, mutect2, varscan2
- ART3 | c.514T>G p.F172V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.914); catalogued as COSV100587771; called by muse, mutect2, varscan2
- ASAH2 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs1324389017; called by muse, mutect2, varscan2
- ASAP1 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1334794467, COSV100727266; called by muse, mutect2, varscan2
- ASB1 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs370724967, COSV99223222; called by muse, mutect2, varscan2
- ASB13 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs777809706, COSV63090964; called by muse, mutect2, varscan2
- ASB7 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 36/116 reads (31%) | catalogued as COSV58404157; called by muse, mutect2, varscan2
- ASCC1 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.019); catalogued as rs776694644, COSV100403368; called by muse, varscan2
- ASCC2 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs376359428; called by muse, mutect2, varscan2
- ASCC3 | c.172C>A p.L58M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV100225709, COSV61233194; called by muse, mutect2, varscan2
- ASCL4 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV60816762; called by muse, varscan2
- ASF1A | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57648147, COSV57648957; called by muse, varscan2
- ASF1B | c.228C>T p.A76= | Splice Region (SNP) | VAF 24/61 reads (39%) | catalogued as rs148905948; called by muse, mutect2, varscan2
- ASH1L | c.4325A>C p.K1442T | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV100853413; called by muse, mutect2, varscan2
- ASPH | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV101063853; called by muse, mutect2, varscan2
- ASPHD2 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99313338; called by muse, mutect2, varscan2
- ASPM | c.3979C>T p.R1327* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as rs886039310, CM133216, COSV54126855; called by muse, mutect2, varscan2
- ASPSCR1 | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as rs772283247, COSV100144866; called by muse, mutect2, varscan2
- ASRGL1 | c.776T>C p.V259A | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as rs989026318, COSV100077862; called by muse, mutect2, varscan2
- ASTL | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs775876067, COSV100668383, COSV60904398; called by muse, mutect2, varscan2
- ASTN2 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57749553, COSV57783585; called by muse, mutect2, varscan2
- ASXL3 | c.2293G>A p.A765T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV99324870; called by muse, mutect2, varscan2
- ASZ1 | c.877G>T p.D293Y | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99498014; called by muse, mutect2, varscan2
- ASZ1 | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766424624, COSV99498016; called by muse, mutect2, varscan2
- ATAD2B | c.4034C>A p.P1345H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV53197271; called by muse, mutect2, varscan2
- ATAD3A | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1187881386, COSV100186329, COSV59235656; called by muse, mutect2, varscan2
- ATAD3A | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs376358465; called by muse, mutect2, varscan2
- ATAD3B | c.482C>T p.A161V (on ENST00000308647; = p.A267V on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs571357728, COSV58020964; called by muse, varscan2
- ATAD5 | c.4864A>G p.T1622A | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV100429947; called by muse, mutect2, varscan2
- ATCAY | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.025); catalogued as COSV100008717; called by muse, mutect2, varscan2
- ATF7IP2 | c.1837C>A p.L613I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100202624; called by muse, mutect2, varscan2
- ATG2A | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs755405435, COSV101034340; called by muse, mutect2, varscan2
- ATG2B | c.4712C>T p.T1571I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV55890106; called by muse, mutect2, varscan2
- ATG9A | c.902G>T p.C301F | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100772580; called by muse, mutect2, varscan2
- ATG9B | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.473); catalogued as rs1175239634, COSV52496289; called by muse, mutect2, varscan2
- ATL2 | c.364-2A>G p.X122_splice | Splice Site (SNP) | VAF 13/25 reads (52%) | catalogued as COSV100184645; called by muse, mutect2, varscan2
- ATP10B | c.2981C>T p.A994V | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV100514942; called by muse, mutect2, varscan2
- ATP10B | c.447C>A p.C149* | Nonsense Mutation (SNP) | VAF 29/78 reads (37%) | catalogued as COSV100469397, COSV100469514; called by muse, mutect2, varscan2
- ATP10D | c.690+1G>T p.X230_splice | Splice Site (SNP) | VAF 35/78 reads (45%) | catalogued as COSV99905603; called by muse, mutect2, varscan2
- ATP11C | c.1445C>A p.A482D | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100557902, COSV100558927; called by muse, mutect2, varscan2
- ATP11C | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV100557906; called by muse, mutect2, varscan2
- ATP11C | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.251); catalogued as rs868182848, COSV100990087; called by muse, mutect2, varscan2
- ATP13A2 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100454141; called by muse, mutect2, varscan2
- ATP13A4 | c.61-1G>T p.X21_splice | Splice Site (SNP) | VAF 8/16 reads (50%) | catalogued as COSV99794503; called by muse, varscan2
- ATP13A5 | c.1967G>A p.R656H | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370727916, COSV60865092; called by muse, mutect2, varscan2
- ATP1A1 | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV99814444; called by muse, mutect2, varscan2
- ATP1A2 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1219118149, COSV63402758; called by muse, mutect2, varscan2
- ATP1A2 | c.2082G>T p.Q694H | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100767833; called by muse, mutect2, varscan2
- ATP1A2 | c.2491C>T p.R831W | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100767835; called by muse, mutect2, varscan2
- ATP1A4 | c.2466+2T>C p.X822_splice | Splice Site (SNP) | VAF 31/87 reads (36%) | catalogued as COSV100927546; called by muse, mutect2, varscan2
- ATP1B2 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.097); catalogued as rs771519448, COSV100006887; called by muse, mutect2, varscan2
- ATP1B3 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV99657271; called by muse, mutect2, varscan2
- ATP2A2 | c.1114G>T p.V372L | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100428603; called by muse, mutect2, varscan2
- ATP2A2 | c.1547C>A p.A516D | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100428604; called by muse, mutect2, varscan2
- ATP2A2 | c.1916G>A p.G639D | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs866543854, COSV100428606; called by muse, mutect2, varscan2
- ATP2A3 | c.2705C>A p.S902Y | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59228661, COSV99989130; called by muse, mutect2, varscan2
- ATP2A3 | c.1585C>T p.R529C | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as rs1019933954, COSV99989135; called by muse, mutect2, varscan2
- ATP2A3 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs747438391, COSV99989137; called by muse, mutect2, varscan2
- ATP2B3 | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1438705735, COSV54856007; called by muse, mutect2, varscan2
- ATP2B3 | c.3293G>A p.R1098H | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs868906106, COSV99684380; called by muse, mutect2, varscan2
- ATP2B4 | c.3476C>T p.A1159V | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs745882708, COSV100397500; called by muse, mutect2, varscan2
- ATP2C2 | c.2717C>T p.A906V | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT tolerated (0.38); PolyPhen benign (0.028); catalogued as rs200596871; called by muse, mutect2, varscan2
- ATP4A | c.2830G>A p.D944N | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as rs772301702, COSV99382255; called by muse, mutect2, varscan2
- ATP6AP2 | c.176C>A p.S59Y | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV101011496, COSV65797177; called by muse, mutect2, varscan2
- ATP6V0A1 | c.768A>C p.E256D | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.578); catalogued as COSV99230952; called by muse, mutect2, varscan2
- ATP6V1B2 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV99369421; called by muse, mutect2, varscan2
- ATP6V1C1 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV67777757; called by muse, mutect2
- ATP6V1D | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV99370830; called by muse, mutect2, varscan2
- ATP7A | c.2468T>C p.V823A | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100430802; called by muse, mutect2, varscan2
- ATP8A2 | c.2476G>A p.V826I | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99681920; called by muse, mutect2, varscan2
- ATP8B2 | c.3608G>A p.R1203H (on ENST00000672630; = p.R1170H on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.619); catalogued as rs372175672; called by muse, mutect2, varscan2
- ATP9A | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.427); catalogued as COSV100124954; called by muse, mutect2, varscan2
- ATR | c.6686C>T p.P2229L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs112373905; called by muse, mutect2, varscan2
- ATR | c.3073C>T p.R1025C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs980426116, COSV63387433; called by muse, mutect2, varscan2
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- ATRN | c.1511G>A p.S504N | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV99497146; called by muse, mutect2, varscan2
- ATRX | c.6274G>A p.A2092T | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100970762; called by muse, mutect2, varscan2
- ATRX | c.6025G>A p.A2009T | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100970764; called by muse, mutect2, varscan2
- ATRX | c.5825G>A p.S1942N | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as COSV100970767; called by muse, mutect2, varscan2
- ATXN2 | c.3596C>T p.A1199V (on ENST00000550104; = p.A1039V on NM_002973.4) | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs749778825, COSV57984655; called by muse, mutect2, varscan2
- ATXN2 | c.2813C>T p.P938L (on ENST00000550104; = p.P778L on NM_002973.4) | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1361964328, COSV101112751; called by muse, mutect2, varscan2
- AUNIP | c.679G>T p.G227C | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV100961860; called by muse, mutect2, varscan2
- AUTS2 | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748925591, COSV100716861; called by muse, mutect2, varscan2
- AUTS2 | c.2150C>A p.A717D | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV100716864; called by muse, mutect2, varscan2
- AUTS2 | c.2818C>T p.P940S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.73); catalogued as COSV100716868; called by muse, varscan2
- AVEN | c.973+1G>T p.X325_splice | Splice Site (SNP) | VAF 33/83 reads (40%) | catalogued as COSV100145501; called by muse, mutect2, varscan2
- AVL9 | c.160T>C p.W54R | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100594624; called by muse, mutect2, varscan2
- AVP | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs747930681, COSV66671735; called by muse, mutect2, varscan2
- AVPR1A | c.292C>A p.L98M | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs774566062, COSV100146851; called by muse, mutect2, varscan2
- AVPR2 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); catalogued as rs1557100546, CM118234, COSV100509509; called by muse, mutect2, varscan2
- AWAT2 | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.973); catalogued as rs928118155, COSV99339658; called by muse, mutect2, varscan2
- AXL | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.853); catalogued as COSV99996546; called by muse, mutect2, varscan2
- AZGP1 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs770260118, COSV99447909; called by muse, mutect2, varscan2
- AZIN1 | c.1281G>T p.K427N | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV100457546; called by muse, mutect2, varscan2
- AZIN1 | c.320del p.N107Tfs*5 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | catalogued as COSV61480773; called by mutect2, pindel, varscan2
- AZU1 | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99297292; called by muse, varscan2
- B3GALT1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59910195; called by muse, mutect2, varscan2
- B3GAT3 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.134); catalogued as rs746566185, COSV99605913; called by muse, mutect2, varscan2
- B4GALNT1 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.14); catalogued as COSV100356453; called by muse, varscan2
- B4GALNT4 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV100327532; called by muse, mutect2, varscan2
- B4GALNT4 | c.2110C>T p.R704* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as rs546869672, COSV100327538; called by muse, varscan2
- B4GALT3 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100157745; called by muse, mutect2, varscan2
- B4GALT4 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1185275891, COSV100785799; called by muse, mutect2, varscan2
- B4GALT4 | c.263G>T p.S88I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as COSV100785800; called by muse, mutect2, varscan2
- B4GALT4 | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV100785801; called by muse, mutect2, varscan2
- B4GALT5 | c.473G>A p.C158Y | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1478844965, COSV100867016; called by muse, mutect2, varscan2
- B4GAT1 | c.863A>G p.Y288C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100240259; called by muse, mutect2, varscan2
- BABAM2 | c.488dup p.N163Kfs*6 | Frame Shift Ins (INS) | VAF 16/40 reads (40%) | catalogued as rs373964958; called by mutect2, varscan2
- BACH1 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs187935039; called by muse, mutect2, varscan2
- BACH2 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as rs375103380, COSV57612203; called by muse, varscan2
- BACH2 | c.833A>T p.E278V | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99999405; called by muse, mutect2, varscan2
- BACH2 | c.119C>A p.T40N | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99999415; called by muse, mutect2, varscan2
- BAG6 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0.025); catalogued as rs1208570601, COSV99277004; called by muse, mutect2, varscan2
- BAHCC1 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs977663882, COSV57028146; called by muse, mutect2, varscan2
- BAHCC1 | c.7019G>A p.R2340H | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs782007533, COSV100311635, COSV100311683; called by muse, varscan2
- BAIAP3 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs767584126, COSV100181468; called by muse, mutect2, varscan2
- BAIAP3 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs559477186, COSV100181475, COSV60981114; called by muse, mutect2, varscan2
- BAIAP3 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs145863608; called by muse, mutect2, varscan2
- BAIAP3 | c.3100G>A p.A1034T | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1488395333, COSV99136209; called by muse, mutect2, varscan2
- BAMBI | c.484G>T p.G162W | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100977502; called by muse, mutect2, varscan2
- BAP1 | c.1447C>T p.Q483* | Nonsense Mutation (SNP) | VAF 45/119 reads (38%) | catalogued as COSV56234818; called by muse, mutect2, varscan2
- BARD1 | c.1177G>A p.G393S | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99638684; called by muse, mutect2
- BAZ1B | c.4094+1G>T p.X1365_splice | Splice Site (SNP) | VAF 19/52 reads (37%) | catalogued as COSV100289773; called by muse, mutect2, varscan2
- BAZ2B | c.4321A>G p.T1441A | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.056); catalogued as rs1452893699, COSV100600634; called by muse, mutect2, varscan2
- BBOF1 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs759690523, COSV101223845; called by muse, mutect2, varscan2
- BBS10 | c.1963C>A p.P655T | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.072); catalogued as COSV101283394; called by muse, mutect2, varscan2
- BBS10 | c.1079G>A p.C360Y | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99675037; called by muse, mutect2, varscan2
- BBS2 | c.1280G>A p.S427N | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1255992217, COSV99802402; called by muse, mutect2, varscan2
- BBS5 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99751876; called by muse, mutect2, varscan2
- BBS7 | c.341+2T>C p.X114_splice | Splice Site (SNP) | VAF 22/51 reads (43%) | catalogued as COSV52655447; called by muse, mutect2, varscan2
- BBX | c.2065C>A p.L689M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100361546; called by muse, mutect2, varscan2
- BCAP31 | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100798932; called by muse, mutect2, varscan2
- BCAS2 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as rs752538298, COSV101058601, COSV65768008; called by muse, mutect2, varscan2
- BCL11A | c.185T>A p.I62N | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV100185659; called by muse, mutect2, varscan2
- BCL6 | c.2068C>T p.Q690* | Nonsense Mutation (SNP) | VAF 37/78 reads (47%) | catalogued as COSV99215685; called by muse, mutect2, varscan2
- BCL6 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 49/113 reads (43%) | catalogued as COSV99215688; called by muse, mutect2, varscan2
- BCL6 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.033); catalogued as COSV99215690; called by muse, mutect2, varscan2
- BCL7B | c.102G>T p.K34N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99790298; called by muse, mutect2, varscan2
- BCL9 | c.4099G>A p.G1367R | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.998); catalogued as rs782351868, COSV52346237; called by muse, mutect2, varscan2
- BCL9L | c.1354del p.Q452Sfs*11 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs756382429; called by mutect2, varscan2
- BCLAF1 | c.1040T>C p.V347A | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.173); catalogued as rs1197046104, COSV100786683; called by muse, mutect2, varscan2
- BCLAF3 | c.1701G>T p.Q567H | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100503297; called by muse, mutect2, varscan2
- BCOR | c.3791C>T p.A1264V (on ENST00000378444 / NM_001123385.2; = p.A1230V on NM_017745.6) | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1369724987, COSV100653311; called by muse, mutect2, varscan2
- BCOR | c.2977C>T p.R993W | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100653312; called by muse, mutect2, varscan2
- BCORL1 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.177); catalogued as rs1013439381, COSV99499414; called by muse, mutect2, varscan2
- BDKRB2 | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 32/69 reads (46%) | catalogued as COSV60014782; called by muse, mutect2, varscan2
- BECN1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.964); catalogued as rs759611322, COSV100831126; called by muse, mutect2, varscan2
- BEND2 | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV101192003; called by muse, mutect2, varscan2
- BEND2 | c.1059G>A p.M353I | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV101192006; called by muse, varscan2
- BEND3 | c.1924C>T p.R642C | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.887); catalogued as rs1167437884, COSV64681720; called by muse, mutect2, varscan2
- BEND5 | c.591G>A p.M197I | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.775); catalogued as COSV100884110; called by muse, mutect2, varscan2
- BEND7 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV100346695; called by muse, mutect2, varscan2
- BEST2 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754854813, COSV99244403; called by muse, varscan2
- BEST2 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV99244408; called by muse, varscan2
- BEST2 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.053); catalogued as rs780198148, COSV50378398; called by muse, mutect2, varscan2
- BEST3 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200668742, COSV58299957; called by muse, mutect2, varscan2
- BHLHE40 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs773058967, COSV56576441; called by muse, mutect2, varscan2
- BICC1 | c.1643G>A p.G548D | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99570513; called by muse, mutect2, varscan2
- BICC1 | c.2597G>A p.G866D | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.43); catalogued as COSV54062961, COSV54065235; called by muse, mutect2
- BICDL1 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs201940570, COSV99985827; called by muse, varscan2
- BICDL2 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1164828218, COSV101199423; called by muse, varscan2
- BICRAL | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.421); catalogued as COSV100018051; called by muse, mutect2, varscan2
- BICRAL | c.1909G>T p.A637S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV100018054; called by muse, mutect2, varscan2
- BIK | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99295668; called by muse, mutect2, varscan2
- BIN1 | c.452A>G p.D151G | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99387984; called by muse, mutect2, varscan2
- BIRC6 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101428280, COSV70206915; called by muse, varscan2
- BIRC6 | c.4340C>A p.S1447Y | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV101428282, COSV70197835; called by muse, mutect2, varscan2
- BIRC6 | c.9644C>A p.P3215H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101428283; called by muse, mutect2, varscan2
- BIRC6 | c.12824G>T p.S4275I | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.361); catalogued as COSV101428284; called by muse, mutect2, varscan2
- BIRC6 | c.14017T>A p.W4673R | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101428285; called by muse, varscan2
- BIVM-ERCC5 | c.1829G>A p.S610N | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV100863749; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4454C>T p.A1485V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.972); catalogued as COSV100863750; called by muse, varscan2
- BLM | c.291G>T p.Q97H | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100757212; called by muse, mutect2, varscan2
- BLMH | c.313del p.W105Gfs*11 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | catalogued as COSV55587541; called by mutect2, pindel, varscan2
- BLOC1S6 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 35/67 reads (52%) | catalogued as rs553672719, COSV99593393; called by muse, mutect2, varscan2
- BLVRA | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs746796433, COSV99645997; called by muse, mutect2, varscan2
- BLVRA | c.694C>A p.H232N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.089); catalogued as COSV99645999; called by muse, mutect2, varscan2
- BLZF1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs369684533, COSV100250614; called by mutect2, varscan2
- BMP4 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs748940819, COSV55415276; called by muse, varscan2
- BMP4 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV99816930; called by muse, varscan2
- BMP4 | c.302G>T p.S101I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as COSV99816931; called by muse, mutect2, varscan2
- BMP7 | c.1033C>A p.Q345K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.96); PolyPhen benign (0.301); catalogued as rs1311095003, COSV101215961; called by muse, mutect2, varscan2
- BMPER | c.567T>G p.C189W | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99779588; called by muse, mutect2, varscan2
- BMPER | c.1978G>A p.V660I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs376351419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMPR2 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as COSV101001492; called by muse, mutect2, varscan2
- BMPR2 | c.1010G>T p.R337I | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV65810379, COSV65813082; called by muse, mutect2, varscan2
- BMS1 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 97/258 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs764818907, COSV100996700; called by muse, mutect2, varscan2
- BMS1 | c.2773C>T p.R925C | Missense Mutation (SNP) | VAF 127/278 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766760047, COSV65734033; called by muse, mutect2, varscan2
- BMT2 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as rs765928225, COSV99774623; called by muse, mutect2, varscan2
- BNC1 | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1236437205, COSV100597188; called by muse, mutect2, varscan2
- BNC2 | c.2429C>T p.S810L | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as rs769262078, COSV101033217; called by muse, mutect2, varscan2
- BOC | c.740G>T p.S247I | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV99848699; called by muse, mutect2, varscan2
- BOD1L1 | c.7390G>T p.V2464L | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.026); catalogued as COSV99239338; called by muse, mutect2, varscan2
- BOD1L1 | c.6166A>G p.T2056A | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99239342; called by muse, mutect2, varscan2
- BOD1L1 | c.5381C>T p.T1794M | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1310527293, COSV99239347; called by muse, mutect2, varscan2
- BOD1L1 | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99239350; called by muse, mutect2, varscan2
- BOLA3 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.478); catalogued as rs746179125, COSV99768152; called by muse, mutect2, varscan2
- BPHL | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs533848752, COSV66743922; called by muse, mutect2, varscan2
- BPIFB3 | c.744C>T p.N248= | Splice Region (SNP) | VAF 34/75 reads (45%) | catalogued as rs757049941, COSV64957082; called by muse, mutect2, varscan2
- BPIFB6 | c.306C>A p.F102L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.666); catalogued as COSV62754499, COSV62755991; called by muse, mutect2, varscan2
- BPNT2 | c.283A>G p.K95E | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1340139892, COSV99389023; called by muse, mutect2, varscan2
- BRAP | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs770298646, COSV59537780; called by muse, mutect2, varscan2
- BRCA2 | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV101204224, COSV66465255; called by muse, mutect2, varscan2
- BRCA2 | c.4321G>T p.E1441* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV66448570; called by muse, mutect2, varscan2
- BRD1 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53458624, COSV53461430; called by muse, mutect2, varscan2
- BRD1 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV99349754; called by muse, mutect2, varscan2
- BRD4 | c.4003C>T p.R1335* | Nonsense Mutation (SNP) | VAF 44/97 reads (45%) | catalogued as COSV99650623; called by muse, mutect2, varscan2
- BRD4 | c.3551C>T p.P1184L | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.777); catalogued as rs199833998, COSV54586645; called by muse, mutect2, varscan2
- BRD4 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 86/194 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1055405627, COSV99650630; called by muse, mutect2, varscan2
- BRINP1 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs139702957; called by muse, mutect2, varscan2
- BRINP1 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs760997991, COSV56310156; called by muse, mutect2, varscan2
- BRINP1 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT tolerated (1); PolyPhen probably damaging (0.935); catalogued as COSV99775394; called by muse, mutect2, varscan2
- BRINP3 | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs201165374, COSV66513018, COSV66537847; called by muse, mutect2, varscan2
- BRIP1 | c.1579C>T p.L527F | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV99370135; called by muse, mutect2, varscan2
- BRIX1 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV100331401; called by muse, mutect2, varscan2
- BRPF1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs758206363, COSV100121257; called by muse, mutect2, varscan2
- BRPF1 | c.1676G>A p.R559H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1468130050, COSV100121260; called by muse, mutect2, varscan2
9,056 further variants in this file (6,280 protein-altering or splice-affecting, 2,549 silent, 227 other) are not listed here.
